Surgical pathology report (de-identified scan), TCGA case TCGA-02-2485, project TCGA-GBM (Glioblastoma Multiforme), tissue source site MD Anderson Cancer Center, specimen TCGA-02-2485-01A (Primary Tumor).

TCGA-02-2485

DIAGNOSIS

(A, B) BRAIN, LEFT PARIETAL REGION, CRANIOTOMY:

GLIOBLASTOMA (WHO GRADE IV). (SEE COMMENT)

COMMENT

Tissue sections show a high-grade diffuse astrocytoma with pleomorphism, brisk mitotic activity, microvascular proliferation, intravascular fibrin thrombi and foci of tumor necrosis.

GROSS DESCRIPTION

(A) LEFT PARIETAL TUMOR - Specimen consists of a single piece of dark-red tissue measuring (6.0 x 3.0 x 2.0 cm). The cut section shows areas of hemorrhage and friable tissue. A representative portion is submitted for frozen section and smear in cassette A1. Additional sections are submitted in cassettes A2-A5.

DX: GLIOBLASTOMA.

(B) LEFT PARIETAL TUMOR - Multiple aggregates of tan hemorrhagic tissue (3.5 x 2.5 x 1.0 cm). Entirely submitted for histologic examination in B1-B4.

CLINICAL HISTORY

None given.

SNOMED CODES

T-A2000, M-94403

Source: NCI Genomic Data Commons file f3354b0c-0fd0-4471-bae2-ec1e5da3ab3f (TCGA-02-2485.5B0BE7BB-15B5-429B-9BC0-94E435C1A164.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).